Somatic mutation profile of tumor specimen TCGA-06-0877-01A (aliquot TCGA-06-0877-01A-01D-1492-08) from TCGA case TCGA-06-0877, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 78.7 years (28,760 days).
Specimen TCGA-06-0877-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ad31f4ed-9711-4b14-8972-61b6748477ed.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-0877-10A (Blood Derived Normal), aliquot TCGA-06-0877-10A-01D-1492-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/421c309b-8906-4896-9d3c-6fc4aca2cdb6

The open-access MAF lists 73 somatic variants for this specimen: 56 protein-altering or splice-affecting, 17 silent.
By variant classification: Missense Mutation 47, Silent 17, Nonsense Mutation 4, Splice Region 2, Splice Site 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTG2 | c.113G>A p.R38H | Missense Mutation (SNP) | VAF 40/156 reads (26%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.108); catalogued as rs869312168, COSV61828224; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CDCA7 | c.911G>A p.R304H (on ENST00000347703 / NM_145810.3; = p.R383H on NM_031942.5) | Missense Mutation (SNP) | VAF 84/359 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.563); catalogued as rs772929976, CM157793, COSV60720077; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1126G>A p.G376R (on ENST00000521381 / NM_181523.3; = p.G106R on NM_181504.4) | Missense Mutation (SNP) | VAF 37/115 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519757, COSV57123316, COSV57132021, COSV57133701; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS16 | c.419C>T p.P140L | Missense Mutation (SNP) | VAF 81/268 reads (30%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as rs752666810, COSV56987513, COSV57008464; called by muse, mutect2, varscan2
- ADCY5 | c.967C>T p.R323C | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as COSV71901346; called by muse, mutect2, varscan2
- ADGRE1 | c.1285C>T p.R429W | Missense Mutation (SNP) | VAF 83/327 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as rs376031317, COSV51672479; called by muse, mutect2, varscan2
- AFM | c.1597G>A p.A533T | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as COSV56919978; called by muse, mutect2, varscan2
- ALDH5A1 | c.359G>A p.R120K | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62373425; called by muse, mutect2, varscan2
- AMD1 | c.224G>A p.R75K | Missense Mutation (SNP) | VAF 64/181 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.506); catalogued as COSV64387347; called by muse, mutect2, varscan2
- ATP10B | c.2246G>A p.R749H | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.957); catalogued as rs371457894, COSV59150292; called by muse, mutect2, varscan2
- C3 | c.4398C>A p.Y1466* | Nonsense Mutation (SNP) | VAF 54/239 reads (23%) | catalogued as COSV55568459; called by muse, mutect2, varscan2
- C4B | c.3743G>A p.R1248H | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.007); catalogued as rs770375016; called by mutect2, varscan2
- CD22 | c.2498G>A p.R833Q | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.207); catalogued as rs571005886, COSV50052116; called by muse, mutect2, varscan2
- CHD7 | c.5783A>T p.Q1928L | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.031); catalogued as COSV71109814; called by muse, mutect2, varscan2
- CNTNAP5 | c.2956A>T p.N986Y | Missense Mutation (SNP) | VAF 55/96 reads (57%) | SIFT tolerated (0.83); PolyPhen benign (0.107); catalogued as COSV70484191; called by muse, mutect2, varscan2
- COL6A1 | c.1240A>T p.N414Y | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.77); catalogued as COSV62612907; called by muse, mutect2, varscan2
- CPNE7 | c.1322G>A p.R441Q | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.98); PolyPhen benign (0.091); catalogued as rs745657186, COSV52012617; called by muse, mutect2, varscan2
- DGKG | c.335A>C p.N112T | Missense Mutation (SNP) | VAF 61/234 reads (26%) | SIFT tolerated (0.6); PolyPhen benign (0.034); catalogued as COSV53964618; called by muse, mutect2, varscan2
- DHX32 | c.1725C>G p.F575L | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.182); catalogued as COSV52941905; called by muse, mutect2, varscan2
- DIDO1 | c.253G>A p.G85S | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.664); catalogued as rs138139875, COSV99825974; called by muse, mutect2, varscan2
- ELF5 | c.227G>A p.C76Y (on ENST00000312319 / NM_198381.2; = p.C66Y on NM_001422.4) | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT tolerated (1); PolyPhen probably damaging (0.995); catalogued as COSV56628783, COSV56630367; called by muse, mutect2, varscan2
- EPHA3 | c.2030T>A p.F677Y | Missense Mutation (SNP) | VAF 53/142 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60703826; called by muse, mutect2, varscan2
- ERBB2 | c.3595C>A p.P1199T | Missense Mutation (SNP) | VAF 52/170 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0.145); catalogued as rs779469693, COSV54069598; called by muse, mutect2, varscan2
- GALNT1 | c.315G>A p.G105= | Splice Region (SNP) | VAF 74/218 reads (34%) | catalogued as COSV52452103; called by muse, mutect2, varscan2
- GMIP | c.1781G>A p.R594H | Missense Mutation (SNP) | VAF 42/186 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1264649898, COSV52554793; called by muse, mutect2, varscan2
- GSTA4 | c.177A>C p.E59D | Missense Mutation (SNP) | VAF 64/195 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as COSV63955422; called by muse, mutect2, varscan2
- IRS1 | c.1951A>G p.R651G | Missense Mutation (SNP) | VAF 76/166 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.051); catalogued as COSV59335961; called by muse, mutect2, varscan2
- ITPRID1 | c.434T>C p.V145A | Missense Mutation (SNP) | VAF 95/344 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); catalogued as COSV60073706; called by muse, mutect2, varscan2
- KIF16B | c.1555G>T p.G519W | Missense Mutation (SNP) | VAF 103/369 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61705549; called by muse, mutect2, varscan2
- KIF2B | c.1129del p.E378Rfs*24 | Frame Shift Del (DEL) | VAF 37/163 reads (23%) | catalogued as COSV52131714; called by mutect2, pindel, varscan2
- MAP3K12 | c.2234G>A p.R745H | Missense Mutation (SNP) | VAF 162/327 reads (50%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.211); catalogued as rs149876591; called by muse, mutect2, varscan2
- OPRPN | c.301G>T p.G101C | Missense Mutation (SNP) | VAF 163/485 reads (34%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.378); catalogued as COSV68192848; called by muse, mutect2, varscan2
- OR5D13 | c.715A>T p.T239S | Missense Mutation (SNP) | VAF 69/192 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.309); catalogued as COSV62333531, COSV62334955; called by muse, mutect2, varscan2
- OR5L2 | c.172C>A p.P58T | Missense Mutation (SNP) | VAF 138/450 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV65723904, COSV65725055; called by muse, mutect2, varscan2
- OR5W2 | c.588G>C p.E196D | Missense Mutation (SNP) | VAF 46/133 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as rs770746761, COSV60615861; called by muse, mutect2, varscan2
- OR9G1 | c.412A>T p.K138* | Nonsense Mutation (SNP) | VAF 60/386 reads (16%) | catalogued as COSV56452365; called by muse, mutect2, varscan2
- OR9G1 | c.652C>A p.L218I | Missense Mutation (SNP) | VAF 96/446 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0.068); catalogued as COSV56450124; called by muse, mutect2
- POLR3C | c.319G>A p.V107I | Missense Mutation (SNP) | VAF 62/183 reads (34%) | SIFT tolerated (0.49); PolyPhen benign (0.005); catalogued as COSV61936414; called by muse, mutect2, varscan2
- PTCHD4 | c.684G>T p.K228N | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated (0.43); PolyPhen benign (0.013); catalogued as COSV59790914; called by muse, mutect2, varscan2
- PUM1 | c.441G>C p.L147F | Missense Mutation (SNP) | VAF 96/282 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.993); catalogued as COSV57084640; called by muse, mutect2, varscan2
- RHAG | c.1137A>C p.T379= | Splice Region (SNP) | VAF 10/56 reads (18%) | catalogued as COSV57705317; called by muse, mutect2, varscan2
- RICTOR | c.913G>A p.G305R | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.194); catalogued as COSV57121293; called by muse, mutect2, varscan2
- RIMS2 | c.3855G>C p.M1285I | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.067); catalogued as COSV51701223; called by muse, mutect2, varscan2
- RPS5 | c.136G>T p.A46S | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.068); catalogued as COSV52191370; called by muse, mutect2, varscan2
- RUVBL2 | c.265G>A p.G89S | Missense Mutation (SNP) | VAF 46/163 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs1354933170, COSV55485016; called by muse, mutect2, varscan2
- SERPINA1 | c.17C>T p.S6L | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.133); catalogued as rs140814100, CM900181; ClinVar: other / uncertain significance; called by muse, mutect2, varscan2
- SLC12A1 | c.2428G>A p.V810M | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.206); catalogued as rs751009620, COSV66794361; called by muse, mutect2, varscan2
- SLC24A2 | c.119T>G p.L40* | Nonsense Mutation (SNP) | VAF 81/159 reads (51%) | catalogued as COSV53863777; called by muse, mutect2, varscan2
- TBC1D4 | c.1170+1G>A p.X390_splice | Splice Site (SNP) | VAF 32/107 reads (30%) | catalogued as COSV66490357; called by muse, mutect2, varscan2
- TESK1 | c.1602G>A p.W534* | Nonsense Mutation (SNP) | VAF 29/79 reads (37%) | catalogued as COSV52410964; called by muse, mutect2, varscan2
- TLR6 | c.1873C>T p.R625W | Missense Mutation (SNP) | VAF 81/250 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.022); catalogued as rs375362297; called by muse, mutect2, varscan2
- TMEM132B | c.796C>G p.P266A | Missense Mutation (SNP) | VAF 181/388 reads (47%) | SIFT tolerated (0.19); PolyPhen benign (0.173); catalogued as rs747981993, COSV54752296; called by muse, mutect2, varscan2
- TRPV2 | c.200+1G>A p.X67_splice | Splice Site (SNP) | VAF 15/40 reads (38%) | catalogued as COSV58428102; called by muse, varscan2
- UBN1 | c.619G>A p.D207N | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); catalogued as COSV52166506, COSV52167808; called by muse, mutect2, varscan2
- VPREB1 | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 45/133 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs369071851; called by muse, mutect2, varscan2
- ZNF197 | c.3039C>G p.F1013L | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0.063); catalogued as COSV56076406, COSV56076431; called by muse, mutect2, varscan2
- ADAMTS14 | c.3015C>T p.C1005= | Silent (SNP) | VAF 42/62 reads (68%) | catalogued as rs750110829, COSV64601731; called by muse, varscan2
- AOC3 | c.309G>A p.L103= | Silent (SNP) | VAF 43/131 reads (33%) | catalogued as COSV53826247; called by muse, mutect2, varscan2
- CLIP4 | c.1572C>G p.G524= | Silent (SNP) | VAF 110/228 reads (48%) | catalogued as COSV60748967; called by muse, mutect2, varscan2
- CUX2 | c.1539C>T p.G513= | Silent (SNP) | VAF 3/9 reads (33%) | catalogued as rs942357124, COSV55640007; called by muse, mutect2
- ELP3 | c.1311G>A p.L437= | Silent (SNP) | VAF 42/113 reads (37%) | catalogued as COSV56458898; called by muse, varscan2
- EOMES | c.909C>T p.N303= | Silent (SNP) | VAF 122/266 reads (46%) | catalogued as rs1247512523, COSV55412329; called by muse, mutect2, varscan2
- HTR3B | c.981C>G p.L327= | Silent (SNP) | VAF 41/137 reads (30%) | catalogued as COSV52744277, COSV99492197; called by muse, mutect2, varscan2
- ISLR2 | c.279C>T p.G93= | Silent (SNP) | VAF 32/115 reads (28%) | catalogued as COSV62302063; called by muse, mutect2, varscan2
- LGALS13 | c.330C>T p.Y110= | Silent (SNP) | VAF 49/188 reads (26%) | catalogued as rs763680574, COSV55679864; called by muse, mutect2, varscan2
- MROH9 | c.1071C>T p.S357= | Silent (SNP) | VAF 19/61 reads (31%) | catalogued as rs760239861, COSV63011071; called by muse, mutect2, varscan2
- P2RY4 | c.330C>T p.F110= | Silent (SNP) | VAF 24/34 reads (71%) | catalogued as rs146718292, COSV65736416; called by muse, mutect2, varscan2
- PARD6G | c.411G>A p.P137= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as COSV62062042; called by muse, mutect2, varscan2
- SIPA1L3 | c.3498G>T p.S1166= | Silent (SNP) | VAF 161/614 reads (26%) | catalogued as COSV55913249; called by muse, mutect2, varscan2
- SLC12A3 | c.2592C>T p.F864= (on ENST00000563236 / NM_001126108.2; = p.F873= on NM_000339.3) | Silent (SNP) | VAF 23/98 reads (23%) | catalogued as rs771944220, COSV52632588; called by muse, mutect2, varscan2
- SLC26A4 | c.2208A>G p.Q736= | Silent (SNP) | VAF 51/163 reads (31%) | catalogued as COSV55916340; called by muse, mutect2, varscan2
- TRH | c.168G>A p.R56= | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as rs775338963, COSV57014898; called by muse, mutect2, varscan2
- UGT2B10 | c.1449C>G p.T483= | Silent (SNP) | VAF 96/303 reads (32%) | catalogued as COSV55322076; called by muse, mutect2, varscan2
